Somatic mutation profile of tumor specimen TCGA-WS-AB45-01A (aliquot TCGA-WS-AB45-01A-11D-A40P-10) from TCGA case TCGA-WS-AB45, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA.
Specimen TCGA-WS-AB45-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7dd178d-8c5f-4e7a-8e00-b1828f8936a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WS-AB45-10A (Blood Derived Normal), aliquot TCGA-WS-AB45-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/780bb87a-6219-4fb7-a46d-9144a82f2862

The open-access MAF lists 3,134 somatic variants for this specimen: 2,352 protein-altering or splice-affecting, 716 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,644, Silent 716, Frame Shift Del 484, Nonsense Mutation 79, Frame Shift Ins 78, Splice Site 30, Intron 27, Splice Region 21, RNA 17, In Frame Del 15, 3'UTR 10, 5'Flank 4.

Variants (750 of 3,134; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 15/125 reads (12%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALPL | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs781272386, CM031615, CM050174, COSV66375979; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARSA | c.302del p.G101Afs*7 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs761606317, CM910050, CM990175; ClinVar: pathogenic; called by mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCL2L11 | c.466G>A p.G156R (on ENST00000393256 / NM_138621.5; = p.G96R on NM_006538.5) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775080943, COSV58028355, COSV58033623; called by muse, mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BTD | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507170, CM010782, CM993541, COSV100329440; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDK13 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796451, COSV99475171; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- COQ8A | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs201908721, CM118850; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.3713del p.K1238Rfs*6 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as rs1557362198; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYNC2H1 | c.6910G>A p.A2304T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.094); catalogued as rs747348765, CM133152, COSV62100084; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ELANE | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.599); catalogued as rs387906553, COSV52255164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1057519817, COSV57251850, COSV57256303; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FANCE | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763151358, COSV57690092; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 23/181 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNC | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs387906587, CM114108, COSV57967712; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by mutect2, varscan2
- GABRG2 | c.471del p.A158Lfs*13 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs1554097890; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HAX1 | c.430dup p.V144Gfs*5 | Frame Shift Ins (INS) | VAF 30/95 reads (32%) | catalogued as rs770288337; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199472720, CM043012, CM064074, COSV99325916; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as rs1555037629, COSV63292691; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRT5 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as rs267607448, CM103084, COSV99357833; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- L1CAM | c.924C>T p.G308= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs797044787, CS982242, COSV100648896; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 54/450 reads (12%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- NDE1 | c.733dup p.L245Pfs*24 (on ENST00000577101; = p.L245Pfs*70 on NM_017668.3) | Frame Shift Ins (INS) | VAF 12/87 reads (14%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTCH1 | c.290del p.N97Tfs*20 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | catalogued as rs1554708751, CD066395, CX962597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SCN1A | c.602+1G>A p.X201_splice | Splice Site (SNP) | VAF 20/206 reads (10%) | catalogued as rs794726827, CS032427, CS096271, COSV100321747, COSV57662425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC22A5 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs386134223, CM033027, CM120316, COSV99809649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.6856C>T p.R2286* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as rs312262785, CM091369, COSV55998184; ClinVar: pathogenic; called by mutect2, varscan2
- SUMF1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852847, CM031424, CM1314874, COSV55996224, COSV99794485; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 12/123 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ZBTB18 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1558149913, COSV100700004; ClinVar: pathogenic; called by muse, varscan2
- A2M | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100588485; called by muse, mutect2
- A3GALT2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs768083377, COSV100378138; called by muse, mutect2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs746497630; called by mutect2, varscan2
- AAK1 | c.1301A>G p.K434R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV65907274; called by muse, mutect2
- AATK | c.3793A>G p.T1265A (on ENST00000326724 / NM_001080395.3; = p.T1162A on NM_004920.2) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100352548; called by muse, mutect2, varscan2
- ABAT | c.366G>A p.A122= | Splice Region (SNP) | VAF 27/126 reads (21%) | catalogued as rs866554267, COSV99190892; called by muse, mutect2, varscan2
- ABCA1 | c.4993A>C p.M1665L | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV101036608; called by muse, mutect2, varscan2
- ABCA2 | c.6080C>T p.A2027V (on ENST00000614293; = p.A1997V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs573640596, COSV55802592; called by muse, mutect2, varscan2
- ABCA2 | c.662A>G p.Y221C (on ENST00000614293; = p.Y191C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV99686980; called by muse, mutect2, varscan2
- ABCA3 | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs140114428, COSV57053333; called by muse, mutect2, varscan2
- ABCA4 | c.6637T>C p.S2213P | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV100933042; called by muse, mutect2, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABCC1 | c.2651C>T p.T884M | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs751066573, COSV100578733; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 16/132 reads (12%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCD1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs782458499, COSV99497292; called by muse, mutect2, varscan2
- ABCF1 | c.866C>T p.A289V (on ENST00000326195 / NM_001025091.2; = p.A251V on NM_001090.3) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.121); catalogued as rs768108149, COSV100400735; called by muse, mutect2, varscan2
- ABCF1 | c.917T>C p.L306P (on ENST00000326195 / NM_001025091.2; = p.L268P on NM_001090.3) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100400736; called by muse, mutect2, varscan2
- ABCG5 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs751275236, COSV53211459; called by muse, mutect2
- ABI1 | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 9/120 reads (8%) | catalogued as COSV100697751; called by muse, mutect2
- ABL1 | c.2881C>T p.P961S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as COSV100583530; called by muse, mutect2, varscan2
- ABLIM1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs202220476, COSV53301485, COSV99522116; called by muse, mutect2, varscan2
- ABTB1 | c.584G>A p.C195Y (on ENST00000232744 / NM_172027.3; = p.C53Y on NM_032548.3) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99229619; called by muse, mutect2, varscan2
- AC011462.1 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260556921, COSV99524447; called by muse, mutect2, varscan2
- ACACB | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs779029093, COSV100622416; called by muse, mutect2, varscan2
- ACAD11 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200376706, COSV53894240; called by muse, mutect2, varscan2
- ACE | c.2590T>C p.Y864H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99326510; called by muse, mutect2, varscan2
- ACE | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.704); catalogued as rs747412511, COSV52004839, COSV99326513; called by muse, mutect2, varscan2
- ACHE | c.1288A>C p.S430R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99573787; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACO2 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs755695367, COSV99346915; called by muse, mutect2
- ACSF3 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV100441128; called by muse, mutect2, varscan2
- ACSL5 | c.745-1G>A p.X249_splice (on ENST00000354273; = p.X305_splice on NM_016234.3) | Splice Site (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100634494; called by muse, mutect2, varscan2
- ACTL6A | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99372867; called by muse, mutect2, varscan2
- ACTL6B | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99355455; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS10 | c.1955C>T p.T652M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781822787, COSV54353341; called by muse, mutect2, varscan2
- ADAMTS7 | c.4772G>A p.R1591Q | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs1035181726, COSV101183026; called by muse, mutect2, varscan2
- ADCK2 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99301414; called by muse, mutect2, varscan2
- ADCY10 | c.2224A>T p.K742* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV100896614, COSV63240116; called by muse, mutect2, varscan2
- ADCY5 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs864309483, CM144901, COSV100567383; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100034851; called by muse, mutect2, varscan2
- ADGRA2 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142650653; called by muse, mutect2, varscan2
- ADGRA2 | c.2954del p.L985Pfs*2 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | catalogued as COSV55102877; called by mutect2, pindel, varscan2
- ADGRE2 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs757107458, COSV100215746; called by muse, mutect2, varscan2
- ADGRE3 | c.1813G>T p.V605F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99505883; called by muse, mutect2, varscan2
- ADGRG4 | c.7841C>T p.T2614M | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1161020084, COSV99794540; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADGRG6 | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425955493, COSV99746024; called by muse, mutect2, varscan2
- ADHFE1 | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52553834; called by muse, mutect2, varscan2
- ADIPOR2 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV100840040; called by muse, mutect2, varscan2
- ADM | c.530dup p.S178Efs*19 | Frame Shift Ins (INS) | VAF 18/120 reads (15%) | catalogued as rs773405081; called by mutect2, varscan2
- ADSS1 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542060225, COSV100272132; called by muse, mutect2, varscan2
- AEBP1 | c.2720G>A p.G907D | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470468110, COSV99788486; called by muse, mutect2, varscan2
- AFF1 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs777638243, COSV57117627; called by muse, mutect2, varscan2
- AFG3L2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555672367, COSV99301563; called by muse, mutect2, varscan2
- AGO2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55046481, COSV55050813; called by muse, mutect2, varscan2
- AGPAT5 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99576302; called by muse, varscan2
- AHCTF1 | c.3778C>T p.R1260* (on ENST00000366508; = p.R1234* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 90/376 reads (24%) | catalogued as rs1558223606, COSV58247045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHDC1 | c.2272G>T p.G758C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV99898946; called by muse, mutect2, varscan2
- AHDC1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as rs1020489249, COSV55940003; called by muse, mutect2, varscan2
- AHNAK2 | c.13625T>C p.L4542P | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60909496; called by muse, varscan2
- AIF1L | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99908066; called by muse, mutect2, varscan2
- AIFM3 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367600638; called by muse, mutect2, varscan2
- AIMP1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs956742218, COSV100786123; called by muse, mutect2, varscan2
- AJAP1 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV65449328; called by muse, mutect2, varscan2
- AK7 | c.1486+1G>A p.X496_splice | Splice Site (SNP) | VAF 17/165 reads (10%) | catalogued as rs1364239872, COSV99967038, COSV99967500; called by muse, mutect2, varscan2
- AKAP1 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as rs368765400; called by muse, mutect2
- AKAP12 | c.1705T>C p.S569P | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99482584; called by muse, mutect2, varscan2
- AKAP4 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV62073889; called by muse, mutect2, varscan2
- AKAP5 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs758946070, COSV57742121; called by muse, mutect2, varscan2
- AKAP8 | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.938); catalogued as rs773404765, COSV54103160; called by muse, mutect2, varscan2
- AKAP8L | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758338472, COSV101275733; called by muse, mutect2, varscan2
- AKAP9 | c.9781C>T p.R3261W (on ENST00000359028; = p.R3237W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs749167841, COSV62360743; called by muse, mutect2
- AL136295.1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99937805; called by muse, mutect2, varscan2
- ALAS2 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs780949974, COSV100238021; called by mutect2, varscan2
- ALDH8A1 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV99664487; called by muse, mutect2, varscan2
- ALG12 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | PolyPhen benign (0.19); catalogued as rs752687068, COSV100427001; called by muse, mutect2, varscan2
- ALKAL1 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV62129931; called by muse, mutect2
- ALPI | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs374647501, COSV55014564; called by muse, mutect2, varscan2
- ALPK3 | c.2304dup p.P769Tfs*8 | Frame Shift Ins (INS) | VAF 20/122 reads (16%) | catalogued as rs1351644582; called by mutect2, varscan2
- ALPL | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs138690664, CM980079; called by muse, mutect2, varscan2
- AMER3 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs369736958; called by muse, mutect2, varscan2
- AMIGO3 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777353932, COSV57537600; called by muse, mutect2, varscan2
- AMOT | c.2671G>A p.A891T (on ENST00000371959 / NM_001113490.1; = p.A482T on NM_133265.3) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1453666164, COSV100494783; called by muse, mutect2, varscan2
- AMOT | c.1755G>T p.K585N (on ENST00000371959 / NM_001113490.1; = p.K176N on NM_133265.3) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV59063274; called by muse, mutect2, varscan2
- AMZ1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs754273996, COSV56688375; called by muse, mutect2, varscan2
- ANAPC2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs186490734, COSV59244143; called by muse, mutect2, varscan2
- ANGPTL2 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143434673; called by muse, mutect2, varscan2
- ANK3 | c.5060A>G p.D1687G | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.322); catalogued as COSV99778571; called by muse, mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ANKIB1 | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV99728494; called by muse, mutect2
- ANKRD36B | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.558); catalogued as rs1216493376, COSV99033603; called by muse, mutect2
- ANO7 | c.173G>A p.R58Q (on ENST00000274979; = p.R4Q on NM_001001666.4) | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1381845912, COSV51471322; called by muse, mutect2, varscan2
- AP1S3 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs370314390, COSV57511518; called by muse, mutect2, varscan2
- AP1S3 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755623874, COSV100525102; called by muse, mutect2, varscan2
- AP2A2 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100172563; called by muse, mutect2
- AP3D1 | c.2363G>A p.S788N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100642415; called by muse, mutect2, varscan2
- AP4M1 | c.566dup p.L189Ffs*14 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs1355324982; called by mutect2, varscan2
- APC | c.2085G>T p.Q695H | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99965753; called by muse, mutect2, varscan2
- APC2 | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs1424211536, COSV52016530; called by muse, mutect2, varscan2
- APOM | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs548136627, COSV52988960; called by mutect2, varscan2
- APTX | c.831dup p.H278Tfs*25 (on ENST00000379819 / NM_175073.2; = p.H278Tfs*20 on NM_175069.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | catalogued as rs750145870; called by mutect2, pindel, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs3215969; called by mutect2, varscan2
- ARAP1 | c.1658G>A p.C553Y (on ENST00000393609 / NM_001040118.2; = p.C308Y on NM_015242.4) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100501620; called by muse, mutect2, varscan2
- ARAP3 | c.555del p.T186Pfs*109 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | catalogued as COSV99499851; called by mutect2, pindel, varscan2
- ARFGEF1 | c.5015G>A p.R1672H | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs200392828, COSV51620792; called by muse, mutect2, varscan2
- ARFGEF2 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV100904050; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP28 | c.1153C>T p.L385F (on ENST00000383472 / NM_001366230.1; = p.L226F on NM_001010000.3) | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99148752, COSV99151155; called by muse, varscan2
- ARHGAP30 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773484463, COSV100920150; called by muse, mutect2, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs751388541; called by mutect2, varscan2
- ARHGAP45 | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); catalogued as COSV100490461; called by muse, mutect2, varscan2
- ARHGEF17 | c.3581G>A p.R1194H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376468445; called by muse, mutect2, varscan2
- ARHGEF2 | c.2245C>A p.L749I (on ENST00000361247 / NM_001162383.2; = p.L721I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100560125; called by muse, mutect2, varscan2
- ARHGEF37 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs773756400, COSV100381950; called by muse, mutect2, varscan2
- ARHGEF40 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV53878721; called by muse, mutect2, varscan2
- ARID2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1331723696, COSV57618720; called by muse, mutect2, varscan2
- ARIH2 | c.1257G>A p.K419= | Splice Region (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100711215; called by muse, mutect2, varscan2
- ARMC9 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs780766885, COSV63022496; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAP2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99855828; called by muse, mutect2, varscan2
- ASAP2 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99431802; called by muse, mutect2, varscan2
- ASCL4 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV100661153, COSV60816854; called by muse, mutect2, varscan2
- ASH1L | c.3880C>A p.L1294I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.503); catalogued as COSV100853167; called by muse, mutect2, varscan2
- ASIC4 | c.1130G>A p.R377Q (on ENST00000347842 / NM_182847.3; = p.R396Q on NM_018674.6) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769374214, COSV99704716; called by muse, mutect2, varscan2
- ASMT | c.961C>A p.L321I (on ENST00000381229; = p.L349I on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV67109612; called by muse, mutect2, varscan2
- ASPHD2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53220351, COSV99313135; called by muse, mutect2, varscan2
- ASTN2 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs148576743; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs746676748; called by mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 22/192 reads (11%) | catalogued as rs866490133; called by mutect2, varscan2
- ATE1 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs767594848, COSV56434189, COSV99817451; called by muse, mutect2
- ATF2 | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV51368107; called by muse, mutect2, varscan2
- ATF6B | c.1992del p.S665Rfs*46 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs1562900790; called by mutect2, pindel, varscan2
- ATF7IP2 | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV100202525; called by muse, mutect2, varscan2
- ATG7 | c.1942G>T p.A648S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100606818; called by muse, mutect2, varscan2
- ATG9B | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV65057384; called by muse, mutect2, varscan2
- ATL1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV63296036; called by muse, mutect2, varscan2
- ATOH1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV60037514; called by muse, mutect2, varscan2
- ATP10A | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs146387652; called by muse, mutect2, varscan2
- ATP10B | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs771511270, COSV100469131; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 16/146 reads (11%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATP11A | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281455868, COSV52105527, COSV52110008; called by muse, mutect2, varscan2
- ATP11A | c.2924A>G p.D975G | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52107230; called by muse, mutect2, varscan2
- ATP12A | c.2677T>G p.F893V | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99517110; called by muse, mutect2
- ATP1A2 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63402270, COSV63403737; called by muse, mutect2, varscan2
- ATP1A4 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.152); catalogued as rs753462997, COSV63628151; called by muse, mutect2, varscan2
- ATP2A1 | c.1546G>T p.G516C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837097; called by muse, mutect2, varscan2
- ATP2A2 | c.2687T>C p.M896T | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100428431; called by muse, mutect2
- ATP2B4 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 47/340 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs200430665, COSV100397153; called by muse, mutect2, varscan2
- ATP5PO | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs377497870; called by mutect2, varscan2
- ATP6AP1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100645172, COSV100645186; called by muse, mutect2, varscan2
- ATP6AP1 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.115); catalogued as COSV100645173; called by muse, mutect2, varscan2
- ATXN2 | c.1742_1743insA p.T582Yfs*32 (on ENST00000550104; = p.T422Yfs*32 on NM_002973.4) | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | catalogued as COSV101112610; called by mutect2, pindel, varscan2
- ATXN2L | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs754290857, COSV57368727; called by muse, mutect2, varscan2
- AXIN1 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs546827136, COSV99249382; called by muse, mutect2, varscan2
- B3GALT4 | c.725del p.G242Afs*48 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs779828300; called by mutect2, pindel
- B3GALT5 | c.913dup p.E305Gfs*20 | Frame Shift Ins (INS) | VAF 12/85 reads (14%) | catalogued as rs768270855; called by mutect2, pindel, varscan2
- B3GNT8 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs758478385, COSV99524451; called by muse, mutect2, varscan2
- B4GALNT4 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1232798207, COSV100327236; called by muse, mutect2, varscan2
- B4GALT2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766675284, COSV58842758; called by mutect2, varscan2
- BAAT | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs780894395, COSV99408387; called by muse, mutect2, varscan2
- BACH2 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as rs940966784, COSV99998277; called by muse, mutect2, varscan2
- BAIAP2 | c.1172G>A p.S391N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.701); catalogued as COSV100347586; called by muse, mutect2, varscan2
- BBS9 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV99626357; called by muse, mutect2, varscan2
- BCL2L1 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs766818591, COSV56969952; called by muse, mutect2, varscan2
- BCORL1 | c.3422G>A p.R1141Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs1238653823, COSV99498655; called by muse, mutect2, varscan2
- BCORL1 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748742225, COSV99498657; called by muse, varscan2
- BHLHE22 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV58861582; called by muse, mutect2
- BHMT | c.769A>G p.N257D | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV99165377; called by muse, mutect2, varscan2
- BICDL2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs766741399, COSV54155590; called by muse, mutect2, varscan2
- BICDL2 | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV66369724; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4448C>A p.A1483E | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as COSV100863612; called by muse, mutect2, varscan2
- BMERB1 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100252687, COSV100253187; called by muse, mutect2, varscan2
- BMP2K | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as rs140542686; called by muse, mutect2, varscan2
- BMPR1B | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs912115035, COSV99215447; called by muse, mutect2, varscan2
- BMPR2 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191486486, COSV65807881; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 9/102 reads (9%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel
- BNC1 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs757220105, COSV100596948; called by muse, mutect2, varscan2
- BOD1L1 | c.6724C>T p.R2242* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as rs1350827648, COSV99238541; called by muse, mutect2, varscan2
- BOD1L1 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV99238544; called by muse, mutect2
- BPIFA3 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs766075057, COSV100967005; called by muse, mutect2, varscan2
- BRD1 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349315; called by muse, mutect2, varscan2
- BRF1 | c.1025del p.G342Afs*36 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV104402591; called by mutect2, pindel, varscan2
- BRF1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as COSV100526892; called by muse, mutect2, varscan2
- BRPF1 | c.3433G>A p.V1145I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.33); catalogued as rs1345537243, COSV100115000, COSV100115154; called by muse, mutect2, varscan2
- BRPF3 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs577867309, COSV100325611, COSV60209649; called by muse, mutect2, varscan2
- BSCL2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs916916343, COSV54014886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.6091C>T p.R2031C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs759981264, COSV56522180; called by muse, mutect2, varscan2
- BSN | c.9757C>T p.R3253W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs757268879, COSV56519349; called by muse, mutect2, varscan2
- BTBD11 | c.2474C>T p.T825M (on ENST00000280758 / NM_001018072.2; = p.T362M on NM_001017523.2) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs753438677, COSV99774850; called by mutect2, varscan2
- BTBD7 | c.3292G>T p.G1098C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV100597558, COSV100598026; called by muse, mutect2, varscan2
- BTN2A1 | c.830del p.K277Rfs*18 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs762471828; called by mutect2, pindel, varscan2
- BTN3A3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs574858167, COSV55071633; called by muse, mutect2, varscan2
- BZW1 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68418733; called by muse, mutect2, varscan2
- C10orf71 | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1420239780, COSV100109779, COSV100110607; called by muse, mutect2, varscan2
- C11orf42 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs781116265, COSV56410011; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C1QC | c.356A>C p.Q119P | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV101009405; called by muse, mutect2, varscan2
- C1R | c.1873C>T p.R625C (on ENST00000536053 / NM_001354346.2; = p.R611C on NM_001733.7) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs772664204, COSV101605606; called by muse, mutect2, varscan2
- C2 | c.2249dup p.L750Ffs*39 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | catalogued as rs774429190; called by mutect2, pindel, varscan2
- C5 | c.4522T>C p.F1508L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV99797265; called by muse, mutect2, varscan2
- C5orf38 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as rs1433010407, COSV100121608; called by muse, mutect2
- C7orf26 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100732840; called by muse, mutect2, varscan2
- C7orf26 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.995); catalogued as rs778178395, COSV100732842; called by muse, mutect2, varscan2
- C7orf33 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100188714; called by muse, mutect2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 17/139 reads (12%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C7orf57 | c.620del p.N207Tfs*92 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | catalogued as rs775739111; called by mutect2, pindel
- C8orf34 | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs190887237; called by muse, mutect2, varscan2
- C8orf82 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV52770884, COSV99430387; called by muse, mutect2
- CA14 | c.268_269del p.L90Afs*38 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs1162215409; called by pindel, varscan2
- CABIN1 | c.3236T>C p.M1079T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV99572777; called by muse, mutect2, varscan2
- CABP5 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368985200; called by muse, mutect2, varscan2
- CACNA1A | c.7057G>A p.E2353K | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as rs1050540062, COSV100801258; called by muse, mutect2, varscan2
- CACNA1A | c.5872G>A p.V1958M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749251058, COSV64191850; called by muse, mutect2, varscan2
- CACNA1B | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs570718684; called by muse, mutect2, varscan2
- CACNA1C | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100216036; called by muse, mutect2, varscan2
- CACNA1E | c.2069G>A p.G690D | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1361083258, COSV100701379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as rs769781251, COSV100701380; called by muse, mutect2, varscan2
- CACNA1G | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs748354117, COSV61721260; called by muse, mutect2, varscan2
- CACNA1H | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs781249124, COSV99326449; called by muse, mutect2, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as rs760298114; called by mutect2, varscan2
- CAD | c.3512dup p.Q1172Tfs*37 | Frame Shift Ins (INS) | VAF 30/164 reads (18%) | catalogued as rs760688978; called by mutect2, varscan2
- CAD | c.6502A>G p.T2168A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV99254507; called by muse, mutect2, varscan2
- CALD1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs372385136; called by muse, mutect2, varscan2
- CALD1 | c.1619G>A p.R540H (on ENST00000361675 / NM_033138.4; = p.R285H on NM_004342.7) | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs766829570, COSV100724050; called by muse, mutect2, varscan2
- CALHM5 | c.738dup p.E247* | Frame Shift Ins (INS) | VAF 17/94 reads (18%) | catalogued as rs768528441; called by mutect2, varscan2
- CAMK2G | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.093); catalogued as rs1177359936, COSV59486021; called by muse, mutect2, varscan2
- CAMKK2 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as rs201146989, COSV100242651; called by muse, mutect2, varscan2
- CAPN13 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs765043713, COSV54430300; called by muse, mutect2, varscan2
- CAPN15 | c.2833del p.V945Wfs*29 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as COSV54836525; called by mutect2, pindel, varscan2
- CAPN3 | c.107del p.G36Vfs*21 | Frame Shift Del (DEL) | VAF 15/159 reads (9%) | catalogued as rs768100265; called by mutect2, pindel, varscan2
- CARD10 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.967); catalogued as rs550531365, COSV99324693; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARM1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV100498890; called by muse, mutect2, varscan2
- CARMIL3 | c.3157C>T p.R1053W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748810187, COSV100549309; called by muse, varscan2
- CASKIN1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs917862443, COSV100623845; called by muse, mutect2, varscan2
- CASKIN2 | c.2449G>T p.G817W | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100050162; called by muse, mutect2, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CATIP | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs746655964, COSV56822431; called by mutect2, varscan2
- CAV3 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100373061; called by muse, mutect2, varscan2
- CBFA2T2 | c.1062G>A p.A354= | Splice Region (SNP) | VAF 21/162 reads (13%) | catalogued as rs145536057, COSV100656180; called by muse, mutect2, varscan2
- CBFA2T3 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1450819403, COSV99241183; called by muse, mutect2, varscan2
- CC2D1A | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100528295; called by muse, mutect2, varscan2
- CCAR2 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99254478; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC136 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs193040933; called by muse, mutect2, varscan2
- CCDC171 | c.3461T>G p.L1154R | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1238398298, COSV52635189; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC183 | c.1025G>A p.W342* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as rs749875462, COSV100272932; called by muse, mutect2, varscan2
- CCDC185 | c.161A>C p.E54A | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV100838756; called by muse, mutect2, varscan2
- CCDC27 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs753168734, COSV53898570; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 25/193 reads (13%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC80 | c.2341T>A p.L781M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99244377; called by muse, mutect2, varscan2
- CCDC87 | c.2227G>T p.G743* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100039781; called by muse, mutect2, varscan2
- CCNJ | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1012998176, COSV99796174; called by muse, mutect2, varscan2
- CCNJL | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs777408880, COSV99979256; called by muse, mutect2, varscan2
- CCNL2 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs767154963, COSV68766185; called by muse, mutect2, varscan2
- CCPG1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs201461691, COSV60528399; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs761073142; called by mutect2, varscan2
- CCT6B | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs749788960, COSV58489848; called by muse, mutect2
- CD33 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs150563546; called by muse, mutect2
- CD33 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as COSV99220100; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 31/221 reads (14%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD93 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV99848947; called by muse, mutect2, varscan2
- CDC16 | c.1376+3_1376+6del p.X459_splice | Splice Site (DEL) | VAF 10/87 reads (11%) | catalogued as rs759504424; called by pindel, varscan2
- CDC42BPG | c.2891G>A p.R964Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747436856, COSV61349821; called by muse, mutect2, varscan2
- CDC5L | c.1249_1251del p.S417del | In Frame Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs774713343; called by mutect2, pindel, varscan2
- CDH16 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.403); catalogued as rs558954232, COSV100233686, COSV100233976; called by muse, mutect2, varscan2
- CDH20 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99404531; called by muse, mutect2, varscan2
- CDH22 | c.2365C>T p.H789Y | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs779693530, COSV100952750; called by muse, mutect2, varscan2
- CDH6 | c.1897T>C p.F633L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV99418235; called by muse, mutect2, varscan2
- CDHR3 | c.1937A>G p.Y646C | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100488048; called by muse, mutect2, varscan2
- CDK13 | c.3226G>A p.V1076M | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV99475172; called by muse, mutect2, varscan2
- CDK18 | c.865C>T p.R289C (on ENST00000506784 / NM_212503.3; = p.R259C on NM_002596.4) | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs766539772, COSV63726842; called by muse, mutect2, varscan2
- CDON | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781486713, COSV99700751; called by muse, mutect2, varscan2
- CEBPZ | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs552370367, COSV99305022; called by muse, mutect2, varscan2
- CEBPZ | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs145996359, COSV99305024; called by muse, mutect2, varscan2
- CELSR1 | c.7027A>G p.I2343V | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.268); catalogued as COSV99417054; called by muse, mutect2
- CELSR2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99603187; called by muse, mutect2, varscan2
- CELSR2 | c.6491C>T p.T2164M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775752921, COSV54765919; called by muse, mutect2, varscan2
- CENPI | c.1798C>A p.L600M | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99515062; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP131 | c.2047T>G p.L683V (on ENST00000269392 / NM_001319228.2; = p.L680V on NM_014984.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV99487893; called by muse, mutect2, varscan2
- CEP41 | c.1120T>C p.*374Qext*6 | Nonstop Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99782598; called by muse, mutect2, varscan2
- CEP43 | c.864del p.L289* | Frame Shift Del (DEL) | VAF 28/251 reads (11%) | catalogued as rs1221111290, COSV62760925; called by mutect2, pindel, varscan2
- CEP78 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1422149488, COSV99450030; called by muse, mutect2, varscan2
- CEP83 | c.1022G>T p.R341M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV100352678; called by muse, mutect2, varscan2
- CERK | c.1428del p.K477Rfs*74 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs761362852; called by mutect2, pindel, varscan2
- CERS3 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1030897658, COSV99431398; called by muse, mutect2, varscan2
- CFAP43 | c.4133G>A p.R1378Q | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1240998046, COSV100829083; called by muse, mutect2, varscan2
- CFAP74 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs761233292, COSV54573871; called by muse, mutect2, varscan2
- CFAP91 | c.980A>C p.E327A | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99846863; called by muse, mutect2
- CHAF1A | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761903668, COSV100010890; called by muse, mutect2, varscan2
- CHAT | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1306112783, CM105868, COSV60321866, COSV60328063; called by muse, mutect2, varscan2
- CHD1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99399155; called by muse, mutect2, varscan2
- CHD3 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100390796, COSV57881133; called by muse, mutect2, varscan2
- CHD6 | c.4093G>T p.G1365C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100950615; called by muse, mutect2
- CHD8 | c.4744C>T p.R1582* (on ENST00000646647 / NM_001170629.2; = p.R1303* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | catalogued as rs1555314211, COSV63219557; called by muse, mutect2, varscan2
- CHRM1 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs376730515; called by muse, mutect2, varscan2
- CHRM4 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.348); catalogued as COSV100708741; called by muse, mutect2
- CHRM4 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100708743; called by muse, mutect2, varscan2
- CHRNA1 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV99650204; called by muse, mutect2, varscan2
- CHRNA10 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.34); catalogued as rs2231543, COSV51705109; called by muse, mutect2, varscan2
- CHRNA6 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs375802894; called by mutect2, varscan2
- CHST1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs747016488, COSV57322138; called by muse, mutect2, varscan2
- CHST13 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.156); catalogued as COSV60041532, COSV60042664; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs745406065; called by mutect2, pindel
- CHTF18 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs374092978; called by mutect2, varscan2
- CIAPIN1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs562918898; called by muse, mutect2
- CKB | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1475325487, COSV100818906; called by muse, mutect2, varscan2
- CKMT1B | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs144997771, COSV55852740; called by muse, mutect2
- CLCN7 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99246946; called by muse, mutect2, varscan2
- CLDN7 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as rs773251272, COSV100598059; called by muse, mutect2, varscan2
- CLDND2 | c.370_372del p.V124del | In Frame Del (DEL) | VAF 37/257 reads (14%) | catalogued as rs1051331535; called by mutect2, pindel, varscan2
- CLIC3 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100860337; called by muse, mutect2, varscan2
- CLIP1 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100211305; called by muse, mutect2, varscan2
- CLIP3 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs755962990, COSV100859269; called by muse, mutect2, varscan2
- CLIP4 | c.1185del p.D396Ifs*19 | Frame Shift Del (DEL) | VAF 45/305 reads (15%) | catalogued as rs1332364476; called by mutect2, pindel, varscan2
- CLK3 | c.547C>T p.R183* (on ENST00000395066 / NM_001130028.1; = p.R35* on NM_003992.4) | Nonsense Mutation (SNP) | VAF 18/143 reads (13%) | catalogued as rs1459068786, COSV61413820; called by muse, mutect2, varscan2
- CLMN | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs936371220, COSV54179243; called by muse, mutect2, varscan2
- CLN3 | c.1157C>T p.A386V (on ENST00000360019 / NM_001286104.2; = p.A410V on NM_000086.2) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs369801432; called by muse, mutect2, varscan2
- CLOCK | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV100011625; called by muse, mutect2, varscan2
- CMYA5 | c.9824C>T p.P3275L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs763085801, COSV71404358; called by muse, mutect2, varscan2
- CNBD1 | c.1263del p.E422Kfs*25 | Frame Shift Del (DEL) | VAF 60/537 reads (11%) | catalogued as rs748250735; called by mutect2, pindel, varscan2
- CNDP1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs762793335, COSV100722206; called by muse, mutect2, varscan2
- CNGA1 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV62053243; called by muse, mutect2
- CNNM3 | c.1888G>A p.V630M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs754286149, COSV59709605; called by muse, mutect2, varscan2
- CNOT3 | c.1999T>C p.S667P | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.757); catalogued as COSV99651552; called by muse, mutect2, varscan2
- CNR1 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.386); catalogued as rs967383969, COSV100759164, COSV62986321; called by muse, mutect2, varscan2
- CNTN3 | c.996G>T p.E332D | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99723462; called by muse, mutect2
- CNTNAP2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs777035367, COSV100663349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201337619, COSV54358557, COSV99473198; called by mutect2, varscan2
- COG2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs200705175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183342777, COSV100596407; called by muse, mutect2, varscan2
- COL11A1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 62/504 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs995254814, COSV62175243; called by muse, mutect2, varscan2
- COL11A2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.818); catalogued as rs866437959, COSV100553520; called by muse, mutect2, varscan2
- COL15A1 | c.3295G>T p.G1099W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66645962; called by muse, mutect2, varscan2
- COL16A1 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs772001417, COSV99593691; called by muse, mutect2, varscan2
- COL20A1 | c.1679del p.P560Rfs*9 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as rs761988638; called by mutect2, pindel, varscan2
- COL20A1 | c.2683del p.L895Yfs*27 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs1339972284; called by mutect2, pindel, varscan2
- COL23A1 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs555500698, COSV101177745; called by muse, mutect2
- COL27A1 | c.2753del p.P918Lfs*9 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs761497355; called by mutect2, pindel, varscan2
- COL4A5 | c.4739C>T p.T1580M | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768320352, COSV60356986, COSV60364945; called by muse, mutect2, varscan2
- COL5A1 | c.4553A>G p.Q1518R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.171); catalogued as COSV100879607; called by muse, mutect2, varscan2
- COL5A1 | c.5393C>T p.T1798M | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs761036527, COSV65673586; called by muse, mutect2, varscan2
- COL5A3 | c.3406G>A p.G1136R | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557640184, COSV53408960; called by muse, mutect2, varscan2
- COL6A2 | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV52428946; called by muse, mutect2, varscan2
- COL7A1 | c.344dup p.N116Qfs*13 | Frame Shift Ins (INS) | VAF 11/74 reads (15%) | catalogued as rs1480404745, COSV100097777; called by mutect2, pindel, varscan2
- COL8A2 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759389508, COSV57440843; called by muse, mutect2, varscan2
- COL9A2 | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1183551087, COSV101028393; called by muse, mutect2, varscan2
- COLQ | c.1195+1G>A p.X399_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | catalogued as rs755782087, CS000217, CS080658, COSV67524367; called by muse, mutect2, varscan2
- COP1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1373217036, COSV58165408; called by muse, mutect2, varscan2
- COPE | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs575079459, COSV99447233; called by muse, mutect2, varscan2
- COPS4 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100018385; called by mutect2, varscan2
- COPS7B | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338843431, COSV62601336; called by muse, mutect2, varscan2
- COQ4 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100306644, COSV55957830; called by muse, mutect2
- COQ5 | c.62T>C p.M21T | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99942200; called by muse, mutect2, varscan2
- CORO7 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs748161669, COSV99227267; called by muse, mutect2, varscan2
- CPA1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs547564304, CM139197, COSV50568895, COSV99163292; called by muse, mutect2, varscan2
- CPA5 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782017298, COSV100812252, COSV62569180; called by muse, mutect2
- CPAMD8 | c.1079G>A p.R360Q (on ENST00000651564; = p.R313Q on NM_015692.5) | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs267605342, COSV99359023; called by muse, mutect2, varscan2
- CPAMD8 | c.901T>C p.Y301H (on ENST00000651564; = p.Y254H on NM_015692.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99359026; called by muse, mutect2, varscan2
- CPD | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1449268016, COSV99852513; called by muse, mutect2, varscan2
- CPEB3 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1194373530, COSV99798688; called by muse, mutect2, varscan2
- CPM | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.695); catalogued as rs538250941, COSV58032165; called by muse, mutect2, varscan2
- CPNE9 | c.1622del p.P541Lfs*56 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs1163581982; called by mutect2, pindel, varscan2
- CPZ | c.1255G>A p.A419T (on ENST00000360986 / NM_001014447.3; = p.A408T on NM_003652.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375155430; called by muse, mutect2, varscan2
- CRB3 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV100375190; called by muse, mutect2, varscan2
- CREB3L1 | c.1271G>A p.S424N | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.954); catalogued as COSV99914852; called by muse, mutect2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRNKL1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs756134981, COSV99843541; called by muse, mutect2
- CROCC | c.4645G>A p.A1549T | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.127); catalogued as rs146661921; called by muse, mutect2, varscan2
- CRYBB1 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs370395737; called by muse, mutect2, varscan2
- CSMD2 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs749349455, COSV53914620; called by muse, mutect2, varscan2
- CSMD3 | c.2247G>A p.W749* (on ENST00000297405 / NM_001363185.1; = p.W645* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | catalogued as COSV99826558; called by muse, mutect2, varscan2
- CSNK1G1 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as rs866598833, COSV100274014; called by mutect2, varscan2
- CSPG4 | c.5983C>T p.R1995W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs529993656, COSV57902610; called by muse, mutect2, varscan2
- CSPG4 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs200809992, COSV57896126; called by muse, mutect2, varscan2
- CSPG5 | c.1195T>C p.C399R | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99273663; called by muse, mutect2, varscan2
- CSRNP3 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.556); catalogued as COSV100085215; called by muse, mutect2, varscan2
- CTAGE1 | c.2222del p.P741Qfs*15 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as rs771653179; called by mutect2, pindel, varscan2
- CTC1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs750352024; called by muse, mutect2, varscan2
- CTNNA2 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100782042; called by muse, varscan2
- CTSA | c.1360-1G>A p.X454_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99509681; called by muse, mutect2, varscan2
- CUEDC1 | c.163A>C p.K55Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV64226118; called by muse, mutect2, varscan2
- CUX1 | c.4109C>T p.A1370V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1172612315, COSV99470669; called by muse, varscan2
- CWF19L2 | c.2559G>A p.M853I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV99978433; called by muse, mutect2, varscan2
- CWH43 | c.1848G>A p.M616I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs1479067972, COSV99892913; called by muse, mutect2, varscan2
- CXorf65 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs1291228092, COSV99340077; called by muse, mutect2, varscan2
- CYBA | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.974); catalogued as COSV99879769; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs756254049; called by pindel, varscan2
- CYC1 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749095706, COSV59644002; called by muse, varscan2
- CYC1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs747866397, COSV59644011; called by muse, varscan2
- CYGB | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs749452700, COSV99505972; called by muse, mutect2, varscan2
- CYLD | c.2305A>T p.I769F | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1489875475, CD051729, COSV61093604, COSV61095598; called by muse, varscan2
- CYP1A2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs761941661, COSV59659344; called by muse, mutect2, varscan2
- CYP1B1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368041729; called by muse, mutect2, varscan2
- CYP3A7 | c.990del p.V331Cfs*30 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | catalogued as COSV60483846; called by mutect2, pindel, varscan2
- CYP8B1 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV60225765; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs751187768; called by mutect2, varscan2
- DAGLA | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as rs764510548, COSV99944047; called by muse, mutect2, varscan2
- DAO | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as rs773218020, COSV57321644, COSV57323645; called by muse, mutect2, varscan2
- DAP3 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs369936772; called by muse, mutect2, varscan2
- DARS2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53406055; called by muse, mutect2, varscan2
- DAW1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100005899; called by muse, mutect2
- DBN1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1248621764, COSV99445614; called by muse, mutect2, varscan2
- DCAF12L1 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100948121; called by muse, mutect2, varscan2
- DCAF12L2 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100758479; called by muse, mutect2
- DCAF15 | c.1640T>A p.V547D | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54328250; called by muse, mutect2, varscan2
- DCAF4L2 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as rs200433622, COSV100150546, COSV60480370; called by muse, mutect2, varscan2
- DCAF5 | c.428A>C p.D143A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); catalogued as COSV100432260; called by muse, mutect2, varscan2
- DCTN1 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100720869; called by muse, mutect2, varscan2
- DDB1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57106070; called by muse, mutect2, varscan2
- DDHD1 | c.1684G>T p.G562* (on ENST00000323669; = p.G759* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV60357711; called by muse, mutect2
- DDHD1 | c.1366C>T p.R456W (on ENST00000323669; = p.R653W on NM_030637.3) | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231979921, COSV60363819; called by muse, varscan2
- DDN | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100304920; called by muse, mutect2, varscan2
- DDX17 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs1320978048, COSV99318617; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 18/118 reads (15%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 4/28 reads (14%) | catalogued as rs755280697; called by pindel, varscan2
- DDX47 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201434704, COSV61912016; called by muse, mutect2, varscan2
- DDX55 | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99147735; called by muse, mutect2, varscan2
- DENND1A | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.265); catalogued as rs1187762062, COSV101011833; called by muse, mutect2, varscan2
- DENND1C | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs373788641; called by muse, mutect2, varscan2
- DENND5A | c.2684del p.K895Sfs*7 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | catalogued as rs1208100549; called by mutect2, varscan2
- DENND5A | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs369437857; called by muse, mutect2, varscan2
- DENND6A | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765063618, COSV100231296; called by muse, varscan2
- DES | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100900342; called by muse, mutect2, varscan2
- DGKA | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100092714; called by muse, mutect2, varscan2
- DGKB | c.2404A>C p.S802R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99336918; called by muse, mutect2, varscan2
- DGKZ | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs538866346, COSV100551128; called by muse, mutect2, varscan2
- DHX29 | c.3464G>A p.R1155H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs142745821; called by muse, mutect2, varscan2
- DHX30 | c.1067G>A p.R356H (on ENST00000445061 / NM_138615.3; = p.R317H on NM_014966.3) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs1202500573, COSV53140499; called by muse, mutect2, varscan2
- DHX30 | c.1625G>A p.R542H (on ENST00000445061 / NM_138615.3; = p.R503H on NM_014966.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53137709; called by muse, mutect2, varscan2
- DIAPH1 | c.1355T>C p.F452S | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99525952; called by muse, mutect2, varscan2
- DICER1 | c.3958G>A p.D1320N | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58627526; called by muse, mutect2, varscan2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV56634983; called by mutect2, pindel, varscan2
- DIP2B | c.3810G>T p.K1270N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99997975; called by muse, varscan2
- DKC1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101059863; called by muse, mutect2, varscan2
- DKK2 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs565067628, COSV99568240; called by muse, mutect2, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLD | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371807385; called by muse, mutect2, varscan2
- DLGAP2 | c.2354G>T p.G785V | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV101421150; called by muse, mutect2, varscan2
- DLGAP3 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs748658137, COSV52392316, COSV52397731; called by mutect2, varscan2
- DLGAP4 | c.1720A>G p.I574V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100210871; called by muse, mutect2, varscan2
- DLL1 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs944362947, COSV64536915; called by muse, mutect2, varscan2
- DLST | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs563480250, COSV53166638; called by muse, mutect2, varscan2
- DLX2 | c.89del p.P30Rfs*115 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs1260289204; called by pindel, varscan2
- DMGDH | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV99668542; called by muse, mutect2, varscan2
- DMXL2 | c.7019T>C p.L2340P | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763598216, COSV99196005; called by muse, mutect2, varscan2
- DNAH11 | c.4211C>T p.A1404V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100177581; called by muse, mutect2, varscan2
- DNAH11 | c.9037G>A p.A3013T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100177585; called by muse, mutect2, varscan2
- DNAH17 | c.4442C>T p.T1481M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs370414556; called by muse, mutect2, varscan2
- DNAH2 | c.4985A>G p.D1662G | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV101209050; called by muse, mutect2
- DNAH3 | c.10010C>T p.T3337M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs530510705, COSV54505745; called by muse, mutect2, varscan2
- DNAH5 | c.13739G>A p.R4580Q | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99445795; called by muse, mutect2, varscan2
- DNAJB12 | c.1069G>A p.A357T (on ENST00000338820; = p.A323T on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.927); catalogued as rs867979745, COSV58759839; called by muse, mutect2, varscan2
- DNAJB2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs201861589, COSV99833725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC11 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53784679; called by muse, mutect2, varscan2
- DNAJC13 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99606728; called by muse, mutect2, varscan2
- DNAJC13 | c.3830A>G p.K1277R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.631); catalogued as COSV53446775, COSV53455102; called by muse, mutect2, varscan2
- DNAJC16 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV101012516; called by muse, mutect2, varscan2
- DNAJC25 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs750942878, COSV100543391, COSV57956675; called by muse, mutect2
- DNAJC9 | c.741A>T p.K247N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV54350222; called by mutect2, varscan2
- DNAL4 | c.52A>G p.T18A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV99326059; called by muse, mutect2, varscan2
- DNASE1L2 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs1417004708, COSV57041678; called by muse, mutect2, varscan2
- DNM1L | c.1916G>A p.R639Q (on ENST00000549701 / NM_012062.5; = p.R602Q on NM_005690.4) | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99845807, COSV99846146; called by muse, mutect2
- DNMBP | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs752522080, COSV60625072; called by muse, mutect2, varscan2
- DNMT1 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs779489678, COSV100531860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK8 | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs146865157; called by muse, mutect2, varscan2
- DOHH | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753023201, COSV51744452; called by muse, mutect2, varscan2
- DOK3 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1283695200, COSV100466879; called by muse, mutect2, varscan2
- DOK4 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); catalogued as COSV99538228; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 16/121 reads (13%) | catalogued as rs35482889; called by mutect2, varscan2
- DPP4 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.935); catalogued as COSV100858718; called by muse, mutect2, varscan2
- DPYSL4 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs770467261, COSV100061905; called by muse, mutect2, varscan2
- DRD1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1431381197, COSV101192522, COSV67104817; called by muse, mutect2, varscan2
- DRD3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.355); catalogued as rs201876283, COSV55680023, COSV99879740; called by muse, mutect2, varscan2
- DRP2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs748167677, COSV100871815; called by muse, mutect2, varscan2
- DRP2 | c.1969T>C p.Y657H | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV65810657; called by muse, mutect2
- DSG4 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs548077429, COSV100355433; called by muse, mutect2, varscan2
- DST | c.14692G>A p.A4898T (on ENST00000361203 / NM_001374722.1; = p.A2486T on NM_015548.5) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.068); catalogued as rs370852578, COSV55001333; called by muse, mutect2, varscan2
- DSTYK | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904484; called by muse, mutect2, varscan2
- DTL | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557946653, COSV65342864; called by muse, mutect2, varscan2
- DTNB | c.995A>G p.H332R | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99976823; called by muse, mutect2, varscan2
- DUOXA2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.815); catalogued as COSV99972895; called by muse, mutect2, varscan2
- DUSP29 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100633242; called by muse, mutect2, varscan2
- DVL3 | c.1761G>T p.K587N | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as COSV99490384; called by muse, mutect2, varscan2
- DYNC1H1 | c.9232C>T p.R3078W | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794543; called by muse, mutect2, varscan2
- DYNC2H1 | c.9242G>A p.R3081H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749753983, COSV62093042; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3059dup p.E1021Gfs*11 | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | catalogued as rs753711667; called by pindel, varscan2
- DZIP1L | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.679); catalogued as COSV100551154; called by muse, mutect2, varscan2
- E2F5 | c.930C>T p.D310= | Splice Region (SNP) | VAF 25/129 reads (19%) | catalogued as rs755426627, COSV99809321; called by muse, mutect2, varscan2
- E2F8 | c.1366A>G p.R456G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100001337; called by muse, mutect2, varscan2
- E2F8 | c.935T>A p.I312N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001340; called by muse, mutect2, varscan2
- ECEL1 | c.1700del p.P567Hfs*48 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as COSV58813737; called by mutect2, pindel, varscan2
- ECPAS | c.3935G>T p.R1312L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); catalogued as rs570259199, COSV52192155; called by muse, mutect2, varscan2
- ECPAS | c.1973T>C p.L658S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV99397636; called by muse, mutect2, varscan2
- EDAR | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM087221, COSV51505234; called by muse, mutect2, varscan2
- EDNRB | c.761C>T p.A254V (on ENST00000377211 / NM_001201397.1; = p.A164V on NM_000115.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as COSV100526296; called by muse, mutect2, varscan2
- EDRF1 | c.2629A>G p.K877E (on ENST00000356792 / NM_001202438.2; = p.K843E on NM_015608.2) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as COSV100523284; called by muse, mutect2
- EED | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs772993565, COSV54556706; called by muse, mutect2, varscan2
- EEF2 | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV100500591; called by muse, mutect2, varscan2
- EFEMP1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs1307987501, COSV62616481; called by muse, mutect2, varscan2
- EFHD1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs773966692, COSV99898323; called by muse, mutect2, varscan2
- EFNA4 | c.36G>T p.W12C | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99664755; called by muse, mutect2, varscan2
- EFNB2 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as rs770833245, COSV55364263; called by muse, mutect2, varscan2
- EGFL8 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1184303311, COSV61247064; called by muse, mutect2, varscan2
- EGLN3 | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV51654116; called by muse, mutect2, varscan2
- EHF | c.342C>T p.N114= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as rs907609906, COSV57668234, COSV57669410; called by muse, mutect2, varscan2
- EHHADH | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51628196; called by muse, mutect2, varscan2
- EHMT2 | c.3569C>T p.A1190V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV57666261; called by muse, mutect2, varscan2
- EIF2AK1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771599948, COSV52236410, COSV99551589; called by mutect2, varscan2
- EIF2AK1 | c.277C>T p.L93= | Splice Region (SNP) | VAF 19/110 reads (17%) | catalogued as rs56396808; called by muse, mutect2, varscan2
- EIF3B | c.2422A>G p.I808V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as rs1403016435, COSV100703568; called by muse, mutect2, varscan2
- EIF4G1 | c.3578G>A p.R1193Q (on ENST00000346169 / NM_198241.3; = p.R998Q on NM_004953.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.536); catalogued as rs1297196131, COSV59990646; called by muse, mutect2, varscan2
- EIF4G2 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100379397; called by muse, mutect2, varscan2
- EIF4G2 | c.41+2T>C p.X14_splice | Splice Site (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100379398; called by muse, mutect2, varscan2
- EIF4G3 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV51677587; called by muse, mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 44/276 reads (16%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELAPOR1 | c.274+1G>A p.X92_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as rs1420464282, COSV100884633; called by muse, mutect2
- ELAVL4 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100836597; called by muse, mutect2, varscan2
- ELOVL2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.767); catalogued as rs554486961, COSV61154096; called by muse, mutect2, varscan2
- ELP1 | c.3527G>T p.S1176I | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65899201; called by muse, mutect2, varscan2
- EML2 | c.819del p.N274Tfs*120 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs1568457333; called by mutect2, pindel, varscan2
- EML5 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as rs758386364, COSV100715123; called by muse, mutect2, varscan2
- EMSY | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100595461; called by muse, mutect2
- ENC1 | c.1047del p.S350Lfs*37 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as COSV56629252; called by mutect2, pindel, varscan2
- ENG | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs748966307, COSV100785227; called by muse, mutect2, varscan2
- ENGASE | c.1638dup p.T547Hfs*45 | Frame Shift Ins (INS) | VAF 44/315 reads (14%) | catalogued as rs759157900; called by mutect2, pindel, varscan2
- ENO1 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV99318632; called by muse, mutect2, varscan2
- ENO3 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99236233; called by muse, mutect2, varscan2
- ENTPD8 | c.1462G>A p.V488I (on ENST00000371506 / NM_001033113.2; = p.V451I on NM_198585.3) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58163101; called by muse, mutect2
- ENTPD8 | c.1370C>T p.P457L (on ENST00000371506 / NM_001033113.2; = p.P420L on NM_198585.3) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.665); catalogued as rs778742069, COSV58164418; called by muse, mutect2, varscan2
- EP300 | c.1969A>C p.M657L | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV99607554; called by muse, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- EPHA10 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757411529, COSV60402341, COSV60404070; called by muse, mutect2, varscan2
- EPRS1 | c.3301-1G>T p.X1101_splice | Splice Site (SNP) | VAF 53/222 reads (24%) | catalogued as COSV100859324; called by muse, mutect2, varscan2
- ERCC4 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs587778284, COSV61311071, COSV61311618; ClinVar: not provided; called by muse, mutect2, varscan2
- ERCC6 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100875723; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERF | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769239795, COSV55896168; called by muse, mutect2
- ERICH3 | c.3479C>T p.T1160M | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as rs779229927, COSV58616542; called by muse, mutect2, varscan2
- ERICH3 | c.1218dup p.P407Tfs*7 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | catalogued as rs1441349703; called by mutect2, pindel, varscan2
- ERMAP | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771020983, COSV60273608; called by muse, mutect2, varscan2
- ERP44 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | catalogued as COSV52430010, COSV52431121; called by muse, mutect2
- ESPN | c.1645G>C p.A549P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV100911351; called by mutect2, varscan2
- ESPNL | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1207015036, COSV100547634; called by muse, mutect2, varscan2
- ESR2 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as rs141940742, COSV50837747; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 54/174 reads (31%) | catalogued as rs775950025; called by mutect2, varscan2
- EVC2 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs373953980; called by muse, mutect2, varscan2
- EXO1 | c.1064G>C p.S355T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100799636; called by muse, mutect2, varscan2
- EXOC3 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV59265839; called by muse, mutect2, varscan2
- EXOC3 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV59265847; called by muse, mutect2, varscan2
- EXOC3L4 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs757105801, COSV66295448, COSV66295527; called by muse, mutect2, varscan2
- EXOC8 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50477655; called by muse, mutect2, varscan2
- EXOSC3 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145622193; called by muse, mutect2
- EXT1 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100983611, COSV65474501; called by muse, mutect2, varscan2
- F13A1 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99342359; called by muse, mutect2, varscan2
- FAF1 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs371330134; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 20/152 reads (13%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM114A1 | c.1594T>G p.C532G | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV100729186; called by muse, mutect2, varscan2
- FAM120A | c.1574C>A p.T525N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99464651; called by muse, mutect2, varscan2
- FAM135B | c.3695G>A p.R1232Q | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs199997922, COSV99419787; called by muse, mutect2, varscan2
- FAM160B2 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs751610973, COSV57157247; called by muse, mutect2, varscan2
- FAM160B2 | c.1537T>C p.F513L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99248768; called by muse, mutect2, varscan2
- FAM177A1 | c.106G>A p.E36K (on ENST00000382406 / NM_001289022.2; = p.E59K on NM_173607.5) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.458); catalogued as rs773329224, COSV55242025; called by muse, mutect2, varscan2
- FAM193A | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.123); catalogued as rs758164159, COSV100218695; called by muse, mutect2
- FAM200A | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs751017963, COSV101282704; called by muse, mutect2, varscan2
- FAM204A | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs148686616; called by muse, mutect2, varscan2
- FAM237A | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs138933434, COSV101405558; called by muse, varscan2
- FAM3A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1399703306, COSV100453585; called by muse, mutect2, varscan2
- FAM43A | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100316382; called by muse, mutect2, varscan2
- FAM53A | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs770980716, COSV57400649; called by muse, mutect2, varscan2
- FAM71A | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs555988865, COSV99674399; called by muse, mutect2, varscan2
- FAM71E1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as COSV100618411; called by muse, mutect2, varscan2
- FAM76A | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1469817961, COSV50548807; called by muse, mutect2, varscan2
- FAM78A | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.059); catalogued as rs1381396017, COSV64844475; called by muse, mutect2
- FAM83C | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs776810089, COSV65583999; called by muse, mutect2, varscan2
- FAM83H | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV101186925; called by muse, mutect2, varscan2
- FAM91A1 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs1271642193, COSV58236071; called by muse, mutect2, varscan2
- FAN1 | c.34del p.R12Gfs*45 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | catalogued as rs752820596; called by mutect2, pindel, varscan2
- FANCG | c.608T>C p.L203S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776489249, COSV62721404; called by muse, mutect2, varscan2
- FAP | c.1622A>G p.Y541C | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929674408, COSV99501789; called by muse, mutect2, varscan2
- FAR1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271953718, COSV100701508; called by muse, mutect2, varscan2
- FARP1 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1169909026, COSV60331665; called by muse, mutect2, varscan2
- FASLG | c.422del p.K141Rfs*3 | Frame Shift Del (DEL) | VAF 71/353 reads (20%) | catalogued as rs35774809; called by mutect2, varscan2
- FASTKD1 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs746515406, COSV71624290; called by muse, mutect2
- FAT1 | c.12518C>T p.T4173M | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs369894626; called by muse, mutect2, varscan2
- FAT1 | c.9293G>T p.R3098M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV101499117, COSV101499457; called by muse, mutect2, varscan2
- FAT4 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67883159; called by muse, mutect2, varscan2
- FAT4 | c.11300C>T p.A3767V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100627399; called by muse, mutect2
- FBF1 | c.1324G>A p.A442T (on ENST00000586717; = p.A456T on NM_001319193.1) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV100044798; called by muse, mutect2, varscan2
- FBXL19 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as rs781616493, COSV100608627; called by muse, mutect2, varscan2
- FBXL19 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.297); catalogued as COSV100590894; called by muse, mutect2, varscan2
- FBXL6 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.382); catalogued as COSV99041726; called by muse, mutect2, varscan2
- FBXO28 | c.76T>G p.S26A | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100837361; called by muse, mutect2, varscan2
- FBXO42 | c.1042G>T p.G348* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100981663; called by muse, mutect2, varscan2
- FCAMR | c.196dup p.R66Kfs*103 | Frame Shift Ins (INS) | VAF 31/257 reads (12%) | catalogued as rs750132652; called by mutect2, pindel, varscan2
- FCGBP | c.6691G>A p.G2231R | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs750153640; called by muse, mutect2
- FCGBP | c.4262A>C p.E1421A | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.32); catalogued as rs782042524, COSV55449363, COSV99661136; called by muse, mutect2
- FEM1A | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54164957; called by muse, mutect2
- FEM1C | c.778del p.R260Efs*7 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | catalogued as rs1561556190; called by mutect2, pindel, varscan2
- FER | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99811788; called by muse, mutect2
- FER1L6 | c.2799del p.R934Gfs*56 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs770147778; called by mutect2, pindel, varscan2
- FER1L6 | c.3062G>A p.C1021Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101205523; called by muse, mutect2
- FGD4 | c.1971del p.K657Nfs*9 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | catalogued as COSV56782969; called by mutect2, pindel, varscan2
- FGFRL1 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99294469; called by muse, mutect2, varscan2
- FHOD3 | c.3847G>A p.D1283N (on ENST00000359247 / NM_001281739.3; = p.D1300N on NM_025135.5) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464406693, COSV99940335; called by muse, mutect2, varscan2
- FIG4 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100019222; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 23/146 reads (16%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FLG | c.3192G>A p.W1064* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as rs755119896, COSV64236309; called by muse, mutect2
- FLG | c.3190T>C p.W1064R | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757324371, COSV64236316; called by muse, mutect2
- FLII | c.3069G>T p.Q1023H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100375102; called by muse, mutect2, varscan2
- FLII | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1338294717, COSV100493499; called by muse, mutect2, varscan2
- FLNA | c.4903C>T p.R1635C | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1400230946, COSV61040067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT1 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761170027, COSV55361360; called by muse, mutect2, varscan2
- FN1 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); catalogued as COSV100116317; called by muse, mutect2, varscan2
- FNDC1 | c.4327dup p.T1443Nfs*81 | Frame Shift Ins (INS) | VAF 9/70 reads (13%) | catalogued as rs1410233255; called by mutect2, varscan2
- FNDC3B | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100393701; called by muse, mutect2, varscan2
- FNIP2 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | catalogued as COSV52437299; called by muse, mutect2, varscan2
- FNIP2 | c.944T>C p.I315T | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100032228; called by muse, varscan2
- FOXB2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942302; called by muse, mutect2, varscan2
- FOXD3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs200810432, COSV100942796; called by muse, mutect2
- FOXE1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 80/735 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1441439043, COSV64301125; called by muse, mutect2, varscan2
- FOXL2 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs758370933, COSV57730775; called by muse, mutect2, varscan2
- FOXN1 | c.1748del p.P583Lfs*5 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | catalogued as rs1298276474; called by mutect2, pindel, varscan2
- FOXN2 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100489016; called by muse, mutect2, varscan2
- FOXP2 | c.6G>C p.M2I | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV100646316; called by muse, mutect2, varscan2
- FOXP4 | c.1543G>A p.V515M (on ENST00000307972 / NM_001012426.1; = p.V502M on NM_138457.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57218690; called by muse, varscan2
- FOXRED1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs771128237, COSV55005485; called by muse, mutect2, varscan2
- FOXRED2 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99340734; called by muse, mutect2
- FREM2 | c.8318A>G p.H2773R | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.236); catalogued as COSV99747167; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMD4B | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101273346; called by muse, mutect2, varscan2
- FRMD4B | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs373504856, COSV68330933; called by muse, mutect2, varscan2
- FRS3 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs142682061; called by muse, mutect2, varscan2
- FRYL | c.8096A>G p.D2699G | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99976045; called by muse, mutect2, varscan2
- FRYL | c.6789dup p.K2264Qfs*11 | Frame Shift Ins (INS) | VAF 40/364 reads (11%) | catalogued as rs1466852277; called by mutect2, pindel, varscan2
- FSHR | c.855-1G>A p.X285_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58636837; called by muse, mutect2, varscan2
- FSIP1 | c.1045A>G p.N349D | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63223710; called by muse, mutect2
- FSTL4 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757606367, COSV54765546; called by muse, mutect2, varscan2
- FUNDC2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.277); catalogued as rs1557288301, COSV100811297; called by muse, mutect2, varscan2
- FUT1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV59567630; called by muse, mutect2
- FUT5 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374990298; called by muse, mutect2, varscan2
- FUZ | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100571025; called by muse, mutect2, varscan2
- FYN | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV99991220; called by muse, mutect2, varscan2
- FZD2 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59528128; called by muse, mutect2
- GABRG1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs940269899, COSV54951321; called by muse, mutect2, varscan2
- GABRR2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140140640; called by muse, mutect2, varscan2
- GADD45GIP1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs921421453; called by muse, mutect2
- GALNS | c.1526C>T p.T509I | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.352); catalogued as rs77419252, COSV99242923; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs1553309006; called by mutect2, pindel, varscan2
- GALNT6 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs202061088, COSV100695329; called by muse, varscan2
- GALNT6 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100695330; called by muse, varscan2
- GAS6 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1008695454, COSV59847557; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GATD1 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs891908947, COSV100168542; called by muse, mutect2, varscan2
- GBF1 | c.5114G>A p.R1705H (on ENST00000369983 / NM_001377137.1; = p.R1704H on NM_004193.3) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482283229, COSV64144738; called by muse, mutect2
- GBP4 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as rs1380058607, COSV63253232; called by muse, mutect2, varscan2
- GCAT | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs372620795; called by muse, mutect2, varscan2
- GCK | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1167124132, CM081272, CM980897, COSV99789866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDF9 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751894227, COSV51526495; called by muse, mutect2, varscan2
- GDPD2 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs758698148, COSV65532803; called by muse, mutect2, varscan2
- GGN | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99287333; called by muse, mutect2, varscan2
- GGN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV53057040; called by muse, mutect2, varscan2
- GGT5 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 30/163 reads (18%) | catalogued as COSV99571297; called by muse, mutect2, varscan2
- GGT5 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs891165405, COSV54072792, COSV99571298; called by muse, mutect2, varscan2
- GIGYF1 | c.2995G>A p.G999R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs778027077, COSV51940625; called by muse, mutect2, varscan2
- GIMAP1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as rs1468419330, COSV56187866; called by muse, mutect2, varscan2
- GJA3 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs751848890, COSV99576276; called by muse, mutect2, varscan2
- GJA4 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs542414709, COSV60724718; called by mutect2, varscan2
- GJB1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.749); catalogued as rs1324941945, COSV100661238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLG1 | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52672059, COSV99215366; called by muse, mutect2, varscan2
- GLG1 | c.1475A>G p.D492G | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as COSV99215367; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 51/156 reads (33%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI2 | c.2057G>A p.G686E (on ENST00000361492 / NM_001374353.1; = p.G703E on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.627); catalogued as rs750226645, COSV100082487; called by muse, mutect2, varscan2
- GLIS3 | c.1684T>C p.Y562H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100173387; called by muse, mutect2, varscan2
- GLRX2 | c.437T>C p.L146S (on ENST00000367439 / NM_197962.3; = p.L147S on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814157; called by muse, mutect2, varscan2
- GLYATL1 | c.227G>A p.R76H (on ENST00000317391 / NM_001354699.1; = p.R107H on NM_080661.4) | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757875991, COSV100265169; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs749150409; called by mutect2, varscan2
- GLYR1 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200221747, COSV58926549; called by muse, varscan2
- GLYR1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs868764205, COSV100424091; called by muse, varscan2
- GNAT3 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 23/151 reads (15%) | catalogued as rs200422530; called by muse, mutect2, varscan2
- GNB1L | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs767598622, COSV61547906, COSV61550112; called by muse, mutect2, varscan2
- GNB5 | c.1115C>A p.T372N (on ENST00000261837 / NM_016194.4; = p.T330N on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV99953153; called by muse, mutect2
- GNE | c.1121T>C p.I374T (on ENST00000396594 / NM_001128227.3; = p.I343T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV64951366; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs1022402829; called by pindel, varscan2
- GNPTAB | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs34946266, CM100333, CS060536; called by muse, mutect2, varscan2
- GOLGA1 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138234842, COSV100332316; called by muse, mutect2, varscan2
- GOLGA5 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs772660824, COSV50832182; called by muse, mutect2, varscan2
- GP1BA | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as rs755192403, COSV56699895; called by muse, mutect2, varscan2
- GPAT3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs777414964, COSV52356357; called by muse, mutect2, varscan2
- GPAT4 | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV101213878; called by muse, mutect2, varscan2
- GPC5 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs772585092, COSV65583951; called by mutect2, varscan2
- GPR107 | c.1640G>A p.R547H (on ENST00000372406 / NM_001136557.2; = p.R499H on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749343893, COSV61281034; called by mutect2, varscan2
- GPR139 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs146922265; called by muse, mutect2, varscan2
- GPR149 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67668776; called by muse, mutect2, varscan2
- GPR150 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101187391; called by muse, mutect2
- GPR158 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as rs1228252841, COSV100892937; called by mutect2, varscan2
- GPR161 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779202531, COSV54789752; called by muse, mutect2, varscan2
- GPR179 | c.4049C>T p.A1350V (on ENST00000621958; = p.A1349V on NM_001004334.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs200212196; called by muse, mutect2
- GPR20 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs559578522, COSV66683945; called by muse, mutect2, varscan2
- GPR25 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV58497752; called by muse, mutect2, varscan2
- GPR3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100927494; called by muse, mutect2, varscan2
- GPR37L1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100938524; called by muse, mutect2, varscan2
- GPR37L1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs773384673, COSV66162951; called by mutect2, varscan2
- GPRIN3 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100310614; called by muse, mutect2, varscan2
- GPSM3 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs775781222, COSV100900425; called by muse, mutect2
- GPT2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs1205102812, COSV60840409; called by muse, mutect2, varscan2
- GPX2 | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV63036025; called by muse, mutect2, varscan2
- GREB1 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as rs749524420, COSV99302333; called by muse, mutect2, varscan2
- GRHL3 | c.1328C>T p.T443M (on ENST00000350501 / NM_198174.3; = p.T448M on NM_021180.3) | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as rs140365190; called by muse, mutect2, varscan2
- GRIN2C | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs940247973, COSV99500633; called by muse, mutect2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs747773579; called by mutect2, varscan2
- GTF2H1 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV99786336; called by muse, mutect2, varscan2
2,384 further variants in this file (1,603 protein-altering or splice-affecting, 715 silent, 66 other) are not listed here.
